Somatic mutation profile of tumor specimen MP2PRT-PAULIE-TMP1-A (aliquot MP2PRT-PAULIE-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAULIE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,093 days).
Specimen MP2PRT-PAULIE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e08ef34-ca42-4c40-bb69-da5e0e42449f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULIE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULIE-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a576c5da-f855-463b-b11e-0c041b1cb856

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 70/374 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 69/344 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 187/654 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs759208513, COSV53573884; called by muse, mutect2, varscan2
- CCDC178 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 142/503 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55793720; called by muse, mutect2, varscan2
- CDH18 | c.2192C>A p.P731H | Missense Mutation (SNP) | VAF 213/459 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56935463; called by muse, mutect2, varscan2
- CFAP99 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 202/596 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as rs1228231575, COSV72648655; called by muse, mutect2, varscan2
- CFTR | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 191/341 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs369040061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.3556G>A p.A1186T (on ENST00000397491 / NM_001253387.1; = p.A1202T on NM_006614.4) | Missense Mutation (SNP) | VAF 114/272 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs201186309, COSV104374520; called by muse, mutect2, varscan2
- DCHS1 | c.9410C>A p.A3137E | Missense Mutation (SNP) | VAF 236/555 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765265323, COSV54997243; called by muse, mutect2, varscan2
- FAT3 | c.6517G>A p.E2173K | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV99960940; called by muse, mutect2
- FLT3 | c.1724A>C p.Q575P | Missense Mutation (SNP) | VAF 107/260 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54065481; called by muse, mutect2, varscan2
- GPT2 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768407590, COSV100412829; called by muse, mutect2, varscan2
- KLRC1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 164/377 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142983959; called by muse, mutect2, varscan2
- MYO9A | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 167/369 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs781035511, COSV100613653; called by muse, mutect2, varscan2
- QRICH2 | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 392/1261 reads (31%) | catalogued as rs1365610023; called by muse, varscan2
- SRP19 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 94/504 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs374209987; called by muse, mutect2, varscan2
- TRPM5 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 97/531 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs374622020, COSV50144287; called by muse, mutect2, varscan2
- TSPYL5 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 248/524 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771287755, COSV59071985; called by muse, varscan2
- VSIG10L2 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 191/391 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs922252896; called by muse, mutect2, varscan2
- ZDHHC5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 25/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1328910163, COSV54705570; called by muse, mutect2
- BRSK1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 168/369 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DNMT1 | c.4700G>A p.G1567D | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVPL | c.4882C>T p.R1628* | Nonsense Mutation (SNP) | VAF 300/963 reads (31%) | called by muse, mutect2, varscan2
- FAT4 | c.4009G>C p.V1337L | Missense Mutation (SNP) | VAF 146/442 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR51B5 | c.527T>A p.F176Y | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.67); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLE7 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 69/344 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ADAMTS3 | c.3096G>T p.V1032= | Silent (SNP) | VAF 125/490 reads (26%) | called by muse, mutect2, varscan2
- CHST6 | c.567C>T p.S189= | Silent (SNP) | VAF 326/659 reads (49%) | catalogued as rs1418379085; called by muse, mutect2, varscan2
- FAM135A | c.1923C>T p.D641= (on ENST00000370479 / NM_001351599.1; = p.D428= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 81/328 reads (25%) | catalogued as rs755719104, COSV99526530; called by muse, mutect2, varscan2
- MC5R | c.645C>T p.H215= | Silent (SNP) | VAF 256/765 reads (33%) | catalogued as rs199802908; called by muse, mutect2, varscan2
- PKNOX1 | c.792C>T p.G264= | Silent (SNP) | VAF 65/472 reads (14%) | catalogued as rs996133808, COSV99372726; called by muse, mutect2, varscan2
- STEAP3 | c.669C>T p.F223= | Silent (SNP) | VAF 273/670 reads (41%) | catalogued as rs766177043, COSV61528848; called by muse, mutect2, varscan2
- USH2A | c.48C>A p.V16= | Silent (SNP) | VAF 129/263 reads (49%) | called by muse, mutect2, varscan2
